Gene-level copy-number profile of tumor specimen CDDP-ABJI-TTP1-A from CDDP_EAGLE case CDDP-ABJI, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73 years.
Specimen CDDP-ABJI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c79fe634-b3b9-43c1-ac53-3988b7181248.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABJI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/00aca75c-4b48-4a27-8524-8e6d965ea0e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 1,979; copy number 2: 29,171; copy number 3: 8,534; copy number 4: 16,562; copy number 5: 1,961; copy number 6: 92; copy number 7: 10; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr1:83,790,280–83,801,465, 1 gene (within-gene range 0–1): AL035706.1.
- chr1:87,328,880–87,348,923, 1 gene: LMO4.
- chr1:88,313,153–88,313,302, 1 gene: AL049861.1.
- chr1:95,351,251–95,381,000, 2 genes: LINC01650, AL445218.1.
- chr1:98,661,701–98,760,500, 1 gene: SNX7.
- chr1:99,646,113–99,699,178, 2 genes: PALMD, HMGB3P10.
- chr1:107,140,007–107,483,458, 1 gene: NTNG1.
- chr1:109,687,814–109,709,039, 2 genes (within-gene range 0–1): GSTM1, AC000032.1.
- chr1:111,200,771–111,256,715, 2 genes (within-gene range 0–1): CHI3L2, CHIAP1.
- chr1:116,423,724–116,478,842, 3 genes (within-gene range 0–1): LINC01762, AL136376.1, Y_RNA.
- chr1:118,614,333–118,713,678, 2 genes: PSMC1P12, AL139148.1.
- chr1:120,849,674–120,914,238, 4 genes (within-gene range 0–2): AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr2:41,143,780–41,157,555, 1 gene: HNRNPA1P57.
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr9:19,705,338–19,705,655, 1 gene (within-gene range 0–1): C11orf98P1.
- chr9:21,403,081–22,214,672, 28 genes: IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr11:54,692,450–54,725,816, 3 genes: OR4A7P, OR4A5, OR4A6P.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,704 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 6 (within-gene range 2–6): AL627309.1.
- chr1:131,025–268,655, 11 genes, copy number 6: CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.2.
- chr1:800,879–817,712, 1 gene, copy number 5 (within-gene range 4–5): AL669831.4.
- chr1:916,865–2,185,395, 87 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:2,184,461–2,413,797, 10 genes, copy number 5: FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10.
- chr1:3,652,516–3,771,645, 6 genes, copy number 5 (within-gene range 4–5): TP73, TP73-AS3, TP73-AS2, TP73-AS1, AL136528.1, CCDC27.
- chr1:4,551,735–4,552,145, 1 gene, copy number 5: Z98747.1.
- chr1:6,412,418–6,784,843, 17 genes, copy number 5: HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, CAMTA1-DT.
- chr1:7,771,296–8,292,263, 18 genes, copy number 5: VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P.
- chr1:9,539,465–9,614,877, 3 genes, copy number 5: SLC25A33, AL954705.1, TMEM201.
- chr1:9,922,113–10,181,239, 12 genes, copy number 5: LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P.
- chr1:10,398,592–10,630,758, 9 genes, copy number 5 (within-gene range 4–5): PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2.
- chr1:10,946,471–11,102,100, 10 genes, copy number 5: C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1.
- chr1:13,474,973–13,516,270, 2 genes, copy number 5: LRRC38, AL354712.1.
- chr1:13,623,184–13,659,910, 2 genes, copy number 5: RNA5SP41, AL359771.1.
- chr1:13,700,198–13,825,079, 1 gene, copy number 5: PRDM2.
- chr1:15,526,813–17,011,928, 87 genes, copy number 5 (broad region; genes not listed).
- chr1:19,484,403–19,680,966, 7 genes, copy number 5 (within-gene range 4–5): MICOS10, RNU4-28P, AL031727.2, NBL1, MICOS10-NBL1, AL031727.1, HTR6.
- chr1:25,338,317–25,362,361, 1 gene, copy number 5 (within-gene range 4–5): TMEM50A.
- chr1:51,059,837–51,060,103, 2 genes, copy number 5: MIR4421, MIR6500.
- chr1:66,924,895–66,988,619, 1 gene, copy number 5: MIER1.
- chr1:70,144,805–70,253,052, 4 genes, copy number 5 (within-gene range 4–5): LRRC40, RN7SL242P, SRSF11, AL353771.1.
- chr1:72,301,472–72,301,829, 1 gene, copy number 5: RPL31P12.
- chr1:189,132,350–190,478,404, 8 genes, copy number 5–6: GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1.
- chr1:190,624,890–190,801,658, 2 genes, copy number 5 (within-gene range 4–5): LINC01720, AL139135.1.
- chr5:22,212,476–23,329,892, 8 genes, copy number 5: AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1.
- chr5:26,880,597–28,214,559, 5 genes, copy number 5: CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1.
- chr5:84,382,424–85,000,315, 2 genes, copy number 5 (within-gene range 4–5): EDIL3-DT, PPIAP79.
- chr5:165,349,030–165,778,689, 2 genes, copy number 5 (within-gene range 4–5): AC008415.1, RN7SKP60.
- chr7:83,355,154–83,664,625, 5 genes, copy number 5: AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2.
- chr8:73,670,441–73,878,854, 2 genes, copy number 5 (within-gene range 3–5): AC027018.1, AC022826.2.
- chr10:42,242,721–42,276,842, 1 gene, copy number 5: AL031601.2.
- chr10:129,467,190–133,391,694, 66 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:11,555–7,713,340, 421 genes, copy number 5 (broad region; genes not listed).
- chr16:7,878,799–32,441,159, 815 genes, copy number 5 (broad region; genes not listed).
- chr16:32,600,299–32,888,874, 23 genes, copy number 5: AC137800.1, AC137800.2, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2, AC142086.2, IGHV2OR16-5, BCAP31P2, SLC6A10P, AC142086.1.
- chr16:46,469,341–47,464,149, 32 genes, copy number 6–8 (within-gene range 4–8): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA.
- chr16:53,055,033–53,329,150, 3 genes, copy number 7 (within-gene range 4–7): CHD9, AC007906.1, AC079416.4.
- chr16:60,346,478–60,499,364, 3 genes, copy number 5–6 (within-gene range 4–6): AC009081.2, AC018554.1, NPAP1L.
- chr16:62,187,540–62,808,706, 5 genes, copy number 5–6: RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1.

Autosomal genes at a single copy (total copy number 1): 1,979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
